Gene-level copy-number profile of tumor specimen TCGA-DK-A3X2-01A from TCGA case TCGA-DK-A3X2, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 85.3 years (31,160 days).
Specimen TCGA-DK-A3X2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.131ee851-5c7b-4e19-acae-9498131f071d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A3X2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d067f05b-3aea-449c-a5af-4444bcb9f0cc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 451; copy number 2: 14,906; copy number 3: 19,390; copy number 4: 16,937; copy number 5: 5,984; copy number 6: 1,851; copy number 7: 299.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A3X2-01A-11D-A22Y-01): tumor purity 0.92, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 265 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:60,906,059–69,987,697, 136 genes, copy number 7 (broad region; genes not listed).
- chr13:93,226,807–94,408,020, 1 gene, copy number 7 (within-gene range 5–7): GPC6.
- chr13:93,818,424–101,720,856, 125 genes, copy number 7 (broad region; genes not listed).
- chr13:101,717,564–101,802,488, 3 genes, copy number 7: AL160153.1, RNU1-24P, HMGB3P7.

Autosomal genes at a single copy (total copy number 1): 451. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
